Somatic mutation profile of tumor specimen TCGA-B0-5698-01A (aliquot TCGA-B0-5698-01A-11D-1669-08) from TCGA case TCGA-B0-5698, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 77.9 years (28,438 days).
Specimen TCGA-B0-5698-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4454bbf1-a712-4e3f-84f5-be5a26270344.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5698-10A (Blood Derived Normal), aliquot TCGA-B0-5698-10A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2875b6df-af63-4e41-befd-4837988007b4

The open-access MAF lists 73 somatic variants for this specimen: 61 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 9, Frame Shift Del 8, Nonsense Mutation 5, Intron 3, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2225G>A p.G742D | Missense Mutation (SNP) | VAF 13/70 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as rs755415626, COSV59205440; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60198590; called by muse, mutect2, varscan2
- ACSL6 | c.1881T>A p.N627K (on ENST00000379240; = p.N652K on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV57296482; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1477A>T p.T493S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as COSV52872101; called by muse, mutect2, varscan2
- CDYL | c.184C>G p.Q62E | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61038822; called by muse, mutect2, varscan2
- CMTR2 | c.1294A>G p.K432E | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV57603087; called by muse, mutect2, varscan2
- CPA6 | c.790C>A p.R264S | Missense Mutation (SNP) | VAF 89/281 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.013); catalogued as COSV52725616; called by muse, mutect2, varscan2
- CYB5RL | c.617A>C p.N206T | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV55277116; called by muse, mutect2, varscan2
- ELF1 | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 52/167 reads (31%) | catalogued as rs749880705, COSV53498149; called by muse, mutect2, varscan2
- EP400 | c.5027G>A p.G1676D | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.634); catalogued as COSV57768672; called by muse, mutect2, varscan2
- EYS | c.1396C>A p.H466N | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1464968889, COSV60981713; called by muse, mutect2, varscan2
- FAM214A | c.2618T>C p.I873T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55923293; called by muse, mutect2, varscan2
- GNAI2 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56493369; called by muse, mutect2, varscan2
- HSPA14 | c.262A>C p.K88Q | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.241); catalogued as COSV65684194; called by muse, mutect2, varscan2
- IGKV2D-24 | c.292C>A p.L98M | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs767972014; called by muse, mutect2, varscan2
- IL1RAP | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.186); catalogued as rs376392541; called by muse, mutect2, varscan2
- ITFG1 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); catalogued as COSV54518528, COSV54528411; called by muse, mutect2, varscan2
- KDM5C | c.3329C>G p.S1110* | Nonsense Mutation (SNP) | VAF 8/11 reads (73%) | catalogued as COSV64764019; called by muse, mutect2, varscan2
- KIF1B | c.5095A>C p.S1699R (on ENST00000377086 / NM_001365952.1; = p.S1653R on NM_015074.3) | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs757564628, COSV55806457; called by muse, mutect2, varscan2
- L2HGDH | c.752G>C p.R251P | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV55556588, COSV55556772; called by muse, mutect2, varscan2
- LRIG2 | c.371T>A p.L124Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV63161565; called by muse, mutect2, varscan2
- MAPK12 | c.457-1G>A p.X153_splice | Splice Site (SNP) | VAF 26/92 reads (28%) | catalogued as COSV53132668; called by muse, mutect2, varscan2
- NALCN | c.4429G>T p.V1477L | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as COSV51927553; called by muse, mutect2, varscan2
- NAV3 | c.4827G>A p.M1609I | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV57072229; called by muse, mutect2, varscan2
- NEO1 | c.3767A>G p.H1256R | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.954); catalogued as rs548041199, COSV56069588; called by muse, mutect2, varscan2
- NPHP4 | c.3024G>T p.E1008D | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV65394253; called by muse, mutect2, varscan2
- OR10H4 | c.153G>A p.W51* | Nonsense Mutation (SNP) | VAF 113/303 reads (37%) | catalogued as COSV59061515; called by muse, mutect2, varscan2
- PBRM1 | c.3664del p.E1222Kfs*5 (on ENST00000296302 / NM_001366071.2; = p.E1197Kfs*5 on NM_018313.5) | Frame Shift Del (DEL) | VAF 38/103 reads (37%) | catalogued as COSV56313900; called by mutect2, pindel, varscan2
- PCDH10 | c.255C>A p.C85* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV52091066; called by muse, mutect2, varscan2
- PDZD3 | c.1105G>A p.A369T (on ENST00000531114; = p.A289T on NM_024791.4) | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52703095; called by muse, mutect2, varscan2
- PIWIL2 | c.373G>C p.V125L | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.014); catalogued as COSV63250721; called by muse, mutect2, varscan2
- PPIL4 | c.1166C>G p.T389S | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.018); catalogued as COSV53566859; called by muse, mutect2, varscan2
- PPP1R26 | c.3265T>G p.F1089V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63355208; called by muse, varscan2
- PRAMEF6 | c.1300A>C p.I434L | Missense Mutation (SNP) | VAF 118/580 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1364695439; called by muse, mutect2, varscan2
- PRPH2 | c.989A>G p.N330S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs781604214, COSV57836639; called by muse, mutect2, varscan2
- PRRT1 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52997847; called by muse, mutect2, varscan2
- PTPRC | c.1092G>C p.E364D | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV61409162; called by muse, mutect2
- PTPRC | c.1094A>T p.Y365F | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV61409170, COSV61409235; called by muse, mutect2
- RIMBP2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV55469132; called by muse, mutect2, varscan2
- SHKBP1 | c.1408G>A p.G470S | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as COSV52538905; called by muse, mutect2, varscan2
- SLITRK6 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68389848; called by muse, mutect2, varscan2
- SMARCD2 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 6/129 reads (5%) | catalogued as rs1025863088, COSV56738394; called by muse, mutect2
- STK32B | c.830T>C p.I277T | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV51480285; called by muse, mutect2, varscan2
- TANC1 | c.2554G>C p.G852R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV55085917; called by muse, mutect2, varscan2
- TMEM63B | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.67); catalogued as COSV52477978; called by muse, mutect2, varscan2
- TMIGD1 | c.60A>C p.L20F | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV61028334; called by muse, mutect2, varscan2
- TTN | c.45559G>T p.A15187S (on ENST00000591111; = p.A7763S on NM_003319.4) | Missense Mutation (SNP) | VAF 44/157 reads (28%) | PolyPhen possibly damaging (0.595); catalogued as COSV59974502; called by muse, mutect2, varscan2
- TTN | c.40729C>T p.R13577W (on ENST00000591111; = p.R6153W on NM_003319.4) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | PolyPhen benign (0.292); catalogued as rs371621174; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- YTHDC2 | c.1793G>C p.S598T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV50738948; called by muse, mutect2, varscan2
- ZBTB20 | c.607G>A p.G203R (on ENST00000474710 / NM_001164342.2; = p.G130R on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV61847055; called by muse, mutect2, varscan2
- ZNF341 | c.1972A>C p.T658P (on ENST00000375200 / NM_001282935.1; = p.T651P on NM_032819.4) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.625); catalogued as COSV61007687; called by muse, mutect2, varscan2
- ABCC6 | c.2960del p.R987Lfs*25 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- ARHGEF15 | c.620del p.P207Lfs*129 | Frame Shift Del (DEL) | VAF 64/248 reads (26%) | called by mutect2, pindel, varscan2
- NBPF15 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 76/396 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- NUP37 | c.157-1_164del p.X53_splice | Splice Site (DEL) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- SLC4A10 | c.218_219del p.R73Kfs*20 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- STAG1 | c.519del p.K173Nfs*13 | Frame Shift Del (DEL) | VAF 55/154 reads (36%) | called by mutect2, pindel, varscan2
- TMEM169 | c.125del p.K42Rfs*43 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- UBIAD1 | c.688dup p.H230Pfs*68 | Frame Shift Ins (INS) | VAF 45/140 reads (32%) | called by mutect2, pindel, varscan2
- ZBTB39 | c.779_782del p.F260Sfs*7 | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- ZNF311 | c.224del p.N75Tfs*7 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | called by mutect2, pindel, varscan2
- CNTN5 | c.3243C>G p.S1081= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV54298336; called by muse, mutect2, varscan2
- CTDP1 | c.1791G>C p.L597= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV50002173; called by muse, mutect2, varscan2
- LTBP4 | c.2967G>A p.R989= (on ENST00000308370 / NM_001042544.1; = p.R952= on NM_003573.2) | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV52579451; called by muse, mutect2, varscan2
- MUC6 | c.1053C>T p.C351= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs763028448, COSV70138598; called by muse, mutect2, varscan2
- NFE2L1 | c.840A>T p.T280= | Silent (SNP) | VAF 63/172 reads (37%) | catalogued as COSV62583028; called by muse, mutect2, varscan2
- STAT2 | c.900C>T p.R300= | Silent (SNP) | VAF 124/332 reads (37%) | catalogued as COSV58474903; called by muse, mutect2, varscan2
- TMEM132D | c.3180C>A p.P1060= | Silent (SNP) | VAF 51/158 reads (32%) | catalogued as COSV67159719; called by muse, mutect2, varscan2
- TRPA1 | c.567T>G p.A189= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV51558899; called by muse, mutect2, varscan2
- XPO6 | c.2898C>A p.I966= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV100485279, COSV58965028; called by muse, mutect2, varscan2
- DAZAP1 | c.1049-934C>T | Intron (SNP) | VAF 32/112 reads (29%) | catalogued as COSV51832632; called by muse, mutect2, varscan2
- PRKACB | c.765+1684G>C | Intron (SNP) | VAF 27/157 reads (17%) | catalogued as rs759985119, COSV65759259; called by muse, mutect2, varscan2
- SUSD4 | c.725-5690C>T | Intron (SNP) | VAF 18/76 reads (24%) | catalogued as COSV59551600; called by muse, mutect2, varscan2
